Somatic mutation profile of tumor specimen C3N-06046-02 (aliquot CPT0438820006) from CPTAC case C3N-06046, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3N-06046-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Penis; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86568102-09cd-49cc-9b28-a4957084fca2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06046-31 (Blood Derived Normal), aliquot CPT0444830004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cdc4c40-02ad-4efe-a7d8-7fd5d54175fd

The open-access MAF lists 77 somatic variants for this specimen: 58 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Nonsense Mutation 5, Intron 3, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEND3 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 161/342 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs781866064, COSV100944697; called by muse, mutect2, varscan2
- CPA3 | c.1064T>C p.I355T | Missense Mutation (SNP) | VAF 34/296 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1380141932; called by muse, mutect2, varscan2
- CSMD3 | c.10276G>T p.D3426Y (on ENST00000297405 / NM_001363185.1; = p.D3257Y on NM_052900.3) | Missense Mutation (SNP) | VAF 49/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52202310; called by muse, mutect2, varscan2
- ERVV-1 | c.627G>A p.W209* | Nonsense Mutation (SNP) | VAF 66/486 reads (14%) | catalogued as rs1040955872; called by muse, mutect2, varscan2
- FAT1 | c.12539C>T p.A4180V | Missense Mutation (SNP) | VAF 133/378 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as rs747017523; called by muse, mutect2, varscan2
- FAT3 | c.12661G>A p.V4221I | Missense Mutation (SNP) | VAF 132/289 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749339528, COSV53082658; called by muse, mutect2, varscan2
- FLNB | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756266678, COSV55884308; called by muse, mutect2, varscan2
- MAN2C1 | c.2848G>A p.V950M | Missense Mutation (SNP) | VAF 124/489 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs3803467; called by muse, mutect2, varscan2
- MGAM | c.3881A>G p.K1294R | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs575918064; called by muse, mutect2
- MICAL2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777658654; called by muse, mutect2, varscan2
- MYT1L | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 75/512 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1334322601; called by muse, mutect2, varscan2
- NCF1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs782002877, COSV56876595; called by muse, mutect2, varscan2
- NELFCD | c.1114G>A p.A372T (on ENST00000602795; = p.A354T on NM_198976.4) | Missense Mutation (SNP) | VAF 115/371 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs372815228; called by muse, mutect2, varscan2
- NLGN1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 312/467 reads (67%) | catalogued as rs1246921076, COSV64341360; called by muse, mutect2, varscan2
- NTNG2 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 128/455 reads (28%) | catalogued as COSV100647443; called by muse, mutect2, varscan2
- OBSCN | c.20475C>G p.F6825L | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV63468599; called by muse, mutect2
- OR10Z1 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 140/512 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100778959; called by muse, mutect2, varscan2
- PLAAT2 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 76/319 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs142689067; called by muse, mutect2, varscan2
- PPP4R3B | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55402285; called by muse, varscan2
- PRDM9 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 190/733 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs375086019; called by muse, varscan2
- PSD4 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 73/546 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as COSV55528870; called by muse, mutect2, varscan2
- RUSC2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 183/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs200615669, COSV100770796; called by muse, mutect2, varscan2
- SERPINA9 | c.661A>T p.T221S | Missense Mutation (SNP) | VAF 191/308 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749711646; called by muse, mutect2, varscan2
- SIPA1L3 | c.5287G>A p.A1763T | Missense Mutation (SNP) | VAF 87/449 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs1035661989, COSV99727534; called by muse, mutect2, varscan2
- TAGLN3 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 42/760 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs763714154; called by muse, mutect2
- ZNF429 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as rs780017355, COSV61914430; called by muse, mutect2, varscan2
- ZNF79 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 128/873 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs1231142061, COSV61071837; called by muse, mutect2, varscan2
- AKAP9 | c.10928A>C p.Q3643P (on ENST00000359028; = p.Q3619P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CASTOR1 | c.649T>C p.S217P | Missense Mutation (SNP) | VAF 127/307 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CLDND2 | c.185C>G p.T62S | Missense Mutation (SNP) | VAF 84/359 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CUL7 | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 356/628 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM186A | c.2393A>C p.E798A | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GPR142 | c.1091C>A p.T364K | Missense Mutation (SNP) | VAF 156/541 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- HEY2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IWS1 | c.465del p.A156Pfs*23 | Frame Shift Del (DEL) | VAF 98/516 reads (19%) | called by mutect2, pindel, varscan2
- LETMD1 | c.916-1G>A p.X306_splice | Splice Site (SNP) | VAF 22/330 reads (7%) | called by muse, mutect2
- LRP2 | c.4483C>A p.Q1495K | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRFIP1 | c.2332G>T p.G778* (on ENST00000392000 / NM_001137552.2; = p.G754* on NM_004735.4) | Nonsense Mutation (SNP) | VAF 72/424 reads (17%) | called by muse, mutect2
- LY75 | c.1974G>A p.K658= | Splice Region (SNP) | VAF 58/248 reads (23%) | called by muse, mutect2, varscan2
- MAP3K13 | c.2874del p.N958Kfs*20 | Frame Shift Del (DEL) | VAF 104/494 reads (21%) | called by mutect2, pindel, varscan2
- MSANTD3 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 144/483 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUC16 | c.43336G>T p.G14446W | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MUC5B | c.5884G>A p.A1962T | Missense Mutation (SNP) | VAF 41/606 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2
- MYH4 | c.1996T>G p.L666V | Missense Mutation (SNP) | VAF 14/413 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- NUTM2G | c.1796dup p.G601Wfs*13 | Frame Shift Ins (INS) | VAF 92/314 reads (29%) | called by mutect2, varscan2
- PABPC4L | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- PDP2 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2
- PPP4R3B | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 104/467 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, varscan2
- RASGRP2 | c.1477G>T p.G493W | Missense Mutation (SNP) | VAF 153/766 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- RC3H2 | c.676_703delinsGACTAGAAC p.R226Dfs*2 | Nonsense Mutation (DEL) | VAF 76/393 reads (19%) | called by pindel, varscan2*
- SEC16B | c.2230G>A p.G744R | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC22A9 | c.1395C>T p.I465= | Splice Region (SNP) | VAF 22/250 reads (9%) | called by muse, mutect2
- TAS1R2 | c.1732C>T p.L578F | Missense Mutation (SNP) | VAF 127/488 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TBL1Y | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TCF23 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 414/638 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAM1L1 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 99/446 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- VPS18 | c.1385A>T p.E462V | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF469 | c.1010G>A p.C337Y | Missense Mutation (SNP) | VAF 61/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRDL2 | c.1227C>T p.V409= (on ENST00000376332 / NM_001304415.1; = p.L428F on NM_015424.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 169/805 reads (21%) | called by muse, mutect2, varscan2
- DOCK4 | c.3126A>T p.V1042= | Silent (SNP) | VAF 79/316 reads (25%) | called by muse, mutect2, varscan2
- DPP8 | c.2655A>G p.Q885= (on ENST00000341861 / NM_001320875.2; = p.Q769= on NM_017743.6) | Silent (SNP) | VAF 97/324 reads (30%) | catalogued as rs767866897; called by muse, mutect2, varscan2
- FBN3 | c.6438A>T p.G2146= | Silent (SNP) | VAF 140/335 reads (42%) | called by muse, mutect2, varscan2
- GJA8 | c.327C>T p.R109= | Silent (SNP) | VAF 170/575 reads (30%) | catalogued as COSV53788847; called by muse, mutect2, varscan2
- GPT | c.567C>T p.Y189= | Silent (SNP) | VAF 166/699 reads (24%) | catalogued as rs144520970; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP10-4 | c.876G>A p.G292= | Silent (SNP) | VAF 20/558 reads (4%) | called by muse, mutect2
- MCM5 | c.1371A>T p.A457= | Silent (SNP) | VAF 102/260 reads (39%) | called by muse, mutect2, varscan2
- MEX3A | c.1341G>A p.E447= | Silent (SNP) | VAF 223/656 reads (34%) | called by muse, mutect2, varscan2
- NOTCH3 | c.6213G>A p.G2071= | Silent (SNP) | VAF 228/956 reads (24%) | called by muse, mutect2, varscan2
- PER3 | c.1926A>G p.P642= | Silent (SNP) | VAF 94/336 reads (28%) | called by muse, mutect2, varscan2
- PTPRC | c.2680C>T p.L894= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as COSV104419415; called by muse, mutect2
- SCP2D1 | c.375G>A p.P125= | Silent (SNP) | VAF 119/411 reads (29%) | catalogued as rs543584703, COSV53856636, COSV53858807; called by muse, mutect2, varscan2
- SH2D3A | c.1032C>G p.V344= | Silent (SNP) | VAF 143/328 reads (44%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.1344G>A p.S448= | Silent (SNP) | VAF 123/283 reads (43%) | catalogued as rs1350266669, COSV59744190; called by muse, mutect2, varscan2
- TDRKH | c.933C>T p.Y311= | Silent (SNP) | VAF 114/395 reads (29%) | catalogued as rs771031491, COSV64316246; called by muse, mutect2, varscan2
- CARMIL3 | c.2707-127C>T | Intron (SNP) | VAF 168/510 reads (33%) | called by muse, mutect2, varscan2
- ITGB3 | c.1260+13G>T | Intron (SNP) | VAF 165/549 reads (30%) | called by muse, mutect2, varscan2
- MGAM | c.4619-8726A>G | Intron (SNP) | VAF 108/691 reads (16%) | called by muse, mutect2, varscan2
